Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A7DU, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A7DU-01A (Primary Tumor).

[page 1 of 2]
TSS Patient ID:

Surgical Date:

Gross Description: 1. Bladder tumor fragments endoscopy recovered with histologic aspect of papillary urothelial carcinoma well/moderate differentiated G1/G2 (low-grade), areas of squamous metaplasia, ulcerated, necrotic, stpT1 (at least).

2. Piece of cystoprostatectomy presenting the urinary bladder with a vegetative tumoral proliferation, developed on trigone, retro-trigone and left wall level, with intramural evolution, peri-OUS, large implanting base and invasive in the whole wall.

Histopathological aspect of infiltrative urothelial cell carcinoma, well/moderately differentiated, G1/G2 (low-grade), with areas of squamous metaplasia, ulcerated, necrotic, intramural evolution and invasion of the entire bladder wall; stpT3. Prostate and seminal vesicles with histological structure preserved.

3. Right ilio-obturator group of 8 (eight) lymph nodes of maximum 1.3 cm in dimensions, with reactive aspect, congestion and sclera-lipomatous dystrophy

4. Left ilio-obturator group of 6 (six) lymph nodes of maximum 1.5 cm with reactive aspect, congestion and sclero-lipomatous dystrophy.

5-6. left and right ureter with preserved histological aspect.

Microscopic Description:

Diagnosis Details: CONCLUSION:

Papillary urothelial cell carcinoma of the bladder, well/moderate differentiated, G1/G2, (low-grade) with areas of squamous metaplasia, stpT3, pNo, pMx (stage III).

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 4 x 4 cm

Tumor features: Ulcerated

Histologic type: Transitional cell carcinoma, papillary

Histologic grade: Moderately to well differentiated

C&CP ICD-O-3
Carcinoma, urothelial NOS
8/20/13
path
Carcinoma, papillary transitional
cell
8/30/13
Site Bladder, trigone
67.0
JH 9/4/13

[page 2 of 2]
Tumor extent: Perivesical tissue (microscopic)

Lymph nodes: 0/14 positive for metastasis (Regional 0/14)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Criteria	lu 8/21/13	Yes	No

Source: NCI Genomic Data Commons file a2866aec-5203-425a-bcfc-e49d326c974c (TCGA-E7-A7DU.BEB0E95C-EDF2-40A5-BB95-588D07369CEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).